Somatic mutation profile of tumor specimen TCGA-17-Z047-01A (aliquot TCGA-17-Z047-01A-01W-0747-08) from TCGA case TCGA-17-Z047, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z047-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b0b7840-ba24-4aab-bbaf-a26e6ef0b993.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z047-11A (Solid Tissue Normal), aliquot TCGA-17-Z047-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbf508aa-eddc-4680-b831-ba8724e6dfff

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 8, Nonsense Mutation 2, Frame Shift Del 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 30/374 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2
- TP53 | c.672+2T>A p.X224_splice | Splice Site (SNP) | VAF 38/100 reads (38%) | hotspot (GDC flag); catalogued as rs1555525703, CS034998, CS0910926, COSV52677962, COSV52797769, COSV53179168; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAH2 | c.5100C>G p.N1700K | Missense Mutation (SNP) | VAF 24/946 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV66726936; called by muse, mutect2
- GLRB | c.701A>G p.K234R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs199963290, COSV100030149; called by muse, mutect2, varscan2
- GRIA2 | c.2075G>A p.W692* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as COSV52396783; called by muse, mutect2, varscan2
- KCNF1 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.213); catalogued as COSV54461912; called by muse, mutect2
- SIX1 | c.665C>G p.P222R | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); catalogued as COSV55961345; called by muse, mutect2, varscan2
- CCDC144A | c.1138T>A p.Y380N | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- COPA | c.1923_1929del p.F641Lfs*71 | Frame Shift Del (DEL) | VAF 37/231 reads (16%) | called by mutect2, pindel, varscan2
- NR0B1 | c.1386G>T p.M462I | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.23); called by muse, mutect2
- PDZRN3 | c.2489A>G p.D830G | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIM2 | c.497A>T p.D166V | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TSC1 | c.452T>A p.L151H | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZBTB20 | c.714C>G p.H238Q (on ENST00000474710 / NM_001164342.2; = p.H165Q on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2
- ZHX3 | c.823C>T p.Q275* | Nonsense Mutation (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- CFAP61 | c.2235C>T p.T745= | Silent (SNP) | VAF 15/286 reads (5%) | catalogued as rs370294355, COSV55618406; called by muse, mutect2
- DAND5 | c.318C>T p.F106= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs1262696399; called by muse, mutect2
- DICER1 | c.879A>G p.R293= | Silent (SNP) | VAF 6/151 reads (4%) | catalogued as CD110309; called by muse, mutect2
- FAM47A | c.825C>T p.D275= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV60494645; called by muse, mutect2, varscan2
- HHATL | c.1386C>G p.L462= | Silent (SNP) | VAF 104/1154 reads (9%) | called by muse, mutect2
- SMARCA2 | c.1245C>T p.Y415= | Silent (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- ZHX3 | c.1171C>T p.L391= | Silent (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- ZNF518A | c.816C>G p.T272= | Silent (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- ZDHHC23 | c.-1C>G | 5'UTR (SNP) | VAF 5/97 reads (5%) | catalogued as COSV57629054, COSV57630290; called by muse, mutect2
